Surgical pathology report (de-identified scan), TCGA case TCGA-XY-A9T9, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Spectrum Health, specimen TCGA-XY-A9T9-01A (Primary Tumor).

[page 1 of 2]
Research Gross Description

-year-old male with testicular lesion

Research Dx

DIAGNOSIS

A. Left testicle, radical orchiectomy:
Seminoma, classic type.

ICD O-3

Seminoma NOS 9061/3
Site: Testis NOS C62.9

QD 4/22/14

Research QC

Tumor T1:
95% tumor nuclei (seminoma)
0% necrosis
5% normal (lymphocytes)

Research Specimen

CASE SUMMARY FOR TESTIS (RADICAL ORCHIECTOMY):

Tumor focality: Unifocal

Tumor size: 6.5 cm

Macroscopic extent of tumor: Confined to the testis

Histologic type: Seminoma, classic type

Margins:

Spermatic cord margin: Negative

Microscopic tumor extension: Confined to the testis

Lymph-Vascular invasion: Not identified

Pathologic Staging (pTNM):

Primary tumor (pT): pT1: Tumor limited to the testis and epididymis without vascular/lymphatic invasion

Regional lymph nodes (pN): pNX: Regional lymph node cannot be assessed

Distant metastasis (pM): pM: Not applicable

Serum tumor markers: LDH- elevated; AFP and HCG: Normal

Additional pathologic findings: Intratubular germ cell neoplasia (IGCN) and parenchymal fibrosis

AJCC Staging (7th edition): pT1 pNX pM not applicable

Specimen Process Time

Blood draw time:

Plasma frozen time:

Serum frozen time:

Buffy coat frozen time:

Cold ischemia start time:

Formalin fixation start time:

Total cold ischemia time: 46 minutes

Formalin fixation stopped time:

Total formalin fixation time: 17 hours

Specimen Weight

Normal

1-151 mg, 2-138 mg

Tumor

1-284 mg, 2-399 mg, 3-323 mg, 4-295 mg

[page 2 of 2]
Specimen Size

Plasma x 2
Serum x1
Buffy coat x1
Cryovials x 6
Normal x 2
Tumor x 4

FFPE x 6
Normal x 2
Tumor x 4

Study

Patient Consent

Yes

Source: NCI Genomic Data Commons file 6e87d3b0-eafc-41da-a23c-8c2db246225a (TCGA-XY-A9T9.AA301591-E319-49F6-994A-C9C1EE3F0D7B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).